Somatic mutation profile of tumor specimen MMRF_1466_1_BM_CD138pos (aliquot MMRF_1466_1_BM_CD138pos_T1_KAS5U_L01372) from MMRF case MMRF_1466, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.6 years (25,798 days).
Specimen MMRF_1466_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3c72160-949c-414d-9553-a56395387ede.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1466_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1466_1_PB_Whole_C2_KAS5U_L01384; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68dc5de4-75a9-414d-8e7d-77dac071c0e4

The open-access MAF lists 102 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 28, Intron 14, Silent 11, 5'UTR 7, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, 5'Flank 2, 3'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 56/168 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAZ2B | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); catalogued as rs373390123; called by muse, mutect2, varscan2
- CAPN5 | c.1290C>T p.Y430= (on ENST00000456580; = p.Y390= on NM_004055.5) | Splice Region (SNP) | VAF 35/128 reads (27%) | catalogued as rs781882976; called by muse, mutect2, varscan2
- MPEG1 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57094093; called by muse, mutect2, varscan2
- NOP2 | c.1252A>G p.N418D (on ENST00000322166 / NM_001258308.2; = p.N414D on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs752863516; called by muse, mutect2, varscan2
- PCDHA5 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as rs1341974527; called by muse, mutect2, varscan2
- PPP2R5D | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758921014, COSV55150259; called by muse, mutect2, varscan2
- PRDM1 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV64844296, COSV64846264; called by muse, mutect2, varscan2
- PSAPL1 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs761015476; called by muse, mutect2, varscan2
- RCC1L | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs147394495; called by muse, mutect2, varscan2
- SEPTIN10 | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61780415; called by muse, mutect2, varscan2
- TPRXL | n.397G>A | Splice Region (SNP) | VAF 50/169 reads (30%) | catalogued as rs1328606298; called by muse, mutect2, varscan2
- ZNF264 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1411980599; called by muse, mutect2, varscan2
- ZNF85 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs1481801349, COSV104394556; called by muse, mutect2, varscan2
- BLOC1S2 | c.373T>A p.L125M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf87 | c.380_385del p.K127_E128del | In Frame Del (DEL) | VAF 40/129 reads (31%) | called by mutect2, pindel, varscan2
- CLCN6 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CXCR4 | c.969_972dup p.S325Vfs*20 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- ENO4 | c.1311C>A p.Y437* (on ENST00000622726; = p.Y434* on NM_001242699.2) | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- EWSR1 | c.1148_1149insAA p.C384Sfs*7 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- FAT3 | c.12374C>T p.T4125M | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- H1-4 | c.191A>T p.K64I | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCFC1 | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGHV1-69D | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by mutect2, varscan2
- IGLV3-1 | c.208_211delinsTAT p.S70Yfs*22 | Frame Shift Del (DEL) | VAF 59/100 reads (59%) | called by pindel, varscan2*
- KCNK6 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- MOCOS | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR12D3 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 96/142 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR4C15 | c.963C>A p.D321E (on ENST00000314644; = p.D267E on NM_001001920.2) | Missense Mutation (SNP) | VAF 218/426 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PAK1IP1 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- PSG5 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- RBM26 | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC38A9 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TENM3 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TSPYL6 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 109/268 reads (41%) | called by muse, mutect2, varscan2
- UCKL1 | c.1448C>A p.S483* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- XRN2 | c.2483C>T p.T828I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY3 | c.66C>T p.V22= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- ATF6B | c.45T>C p.R15= | Silent (SNP) | VAF 149/231 reads (65%) | called by muse, mutect2, varscan2
- CADPS2 | c.978G>A p.S326= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as rs772232660, COSV57348365; called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.198G>T p.L66= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs562646171; called by muse, varscan2
- LDB2 | c.1005C>T p.D335= | Silent (SNP) | VAF 90/186 reads (48%) | catalogued as rs749480922; called by muse, mutect2, varscan2
- MAP3K15 | c.2229G>C p.G743= | Silent (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- PLAT | c.435C>T p.G145= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs141317668, COSV99535149; ClinVar: likely benign; called by muse, mutect2
- RAB39A | c.456G>A p.K152= | Silent (SNP) | VAF 47/218 reads (22%) | called by muse, mutect2, varscan2
- SRRM3 | c.1950C>T p.S650= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs782262141; called by muse, mutect2, varscan2
- TENM1 | c.1869C>T p.C623= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as rs1322148554, COSV64431434, COSV64446882; called by muse, mutect2, varscan2
- ABCB8 | c.95+52A>G | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs774155720; called by muse, varscan2
- ADAMTS6 | c.1370+2823G>A | Intron (SNP) | VAF 44/58 reads (76%) | catalogued as rs865938382; called by muse, mutect2, varscan2
- ADH6 | chr4:99203428 C>A | 3'Flank (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- AGPAT4 | c.*2582G>T | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- ARL14EP | c.-63-746G>T | Intron (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- BEND4 | c.*5597dup | 3'UTR (INS) | VAF 14/29 reads (48%) | called by mutect2, varscan2
- DUOXA2 | c.148-228G>T | Intron (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ERBB4 | c.*1518A>T | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- FAM102B | c.*3850G>A | 3'UTR (SNP) | VAF 14/34 reads (41%) | catalogued as rs921529335; called by muse, mutect2, varscan2
- FAM227B | c.546+268C>G | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- FAM3A | c.-82G>A | 5'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- FAT3 | c.*2404T>C | 3'UTR (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- GIMAP1 | c.43+104G>C | Intron (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2
- GOLGA5 | c.*233G>A | 3'UTR (SNP) | VAF 7/48 reads (15%) | catalogued as rs780902428; called by muse, mutect2, varscan2
- GULP1 | c.844-2497A>G | Intron (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- HGF | c.*3024A>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- HS1BP3 | c.*681G>C | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- IARS1 | c.-90A>C | 5'UTR (SNP) | VAF 115/267 reads (43%) | called by muse, mutect2, varscan2
- IGDCC4 | c.*549G>T | 3'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- KCNK1 | c.*337T>G | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- KCTD16 | c.*947C>G | 3'UTR (SNP) | VAF 12/59 reads (20%) | catalogued as rs996857124; called by muse, mutect2, varscan2
- KIAA1143 | c.*1013G>A | 3'UTR (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- KIF6 | c.*5463G>A | 3'UTR (SNP) | VAF 235/351 reads (67%) | catalogued as rs1002565173; called by muse, mutect2, varscan2
- LMNA | c.-145G>A | 5'UTR (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- MCC | chr5:113488606 C>T | 5'Flank (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- MGAT5 | c.*3863C>T | 3'UTR (SNP) | VAF 31/55 reads (56%) | catalogued as rs1170968567; called by muse, mutect2, varscan2
- MID1 | c.*3747C>G | 3'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- NPHS1 | c.2213-70A>C | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2
- PATJ | c.*197A>T | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- PCDHB10 | c.*438A>T | 3'UTR (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- PCNA | c.-122T>G | 5'UTR (SNP) | VAF 136/236 reads (58%) | called by muse, mutect2, varscan2
- PEX5L | c.*1756G>T | 3'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- PI15 | c.*1392C>A | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- POF1B | c.*446A>T | 3'UTR (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- PPP1R16B | c.*3596G>T | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- PPP5C | c.-7_-6insA | 5'UTR (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- PRKAA2 | c.*2875G>A | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- PRKACB | c.*2130T>G | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+14C>T | Intron (SNP) | VAF 17/71 reads (24%) | called by muse, varscan2
- RAPGEF5 | c.871-233_871-218delinsAG | Intron (DEL) | VAF 9/47 reads (19%) | called by pindel, varscan2*
- RBM5 | c.2095-80G>C | Intron (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- SLC12A5 | c.924-343G>A | Intron (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- SLC7A1 | c.*3722G>A | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- SNTN | c.*368G>A | 3'UTR (SNP) | VAF 53/86 reads (62%) | called by muse, mutect2, varscan2
- SRRM4 | c.*3872C>A | 3'UTR (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- TENT5A | c.*571C>A | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- TERB2 | c.*577T>A | 3'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, varscan2
- TMSB4X | chrX:12975184 C>T | 5'Flank (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- TPTE | c.-3C>T | 5'UTR (SNP) | VAF 90/420 reads (21%) | catalogued as rs754765553; called by muse, mutect2, varscan2
- TRIM24 | c.*4616G>T | 3'UTR (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- WDR89 | c.-12G>C | 5'UTR (SNP) | VAF 108/256 reads (42%) | called by muse, mutect2, varscan2
- ZNF24 | c.568+927A>G | Intron (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- ZNF25 | c.*89T>G | 3'UTR (SNP) | VAF 98/180 reads (54%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-825C>T | Intron (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
